Surgical pathology report (de-identified scan), TCGA case TCGA-IB-8127, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-8127-01A (Primary Tumor).

[page 1 of 5]
MRN:
PHN:
ACB:
DOB/Gender:
Telephone:
Encounter:

Location:
Ordering:

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

Specimen Description

- A. Liver biopsy at
- B. Gallbladder at
- C. Portal lymph nodes at
- D. Whipple's specimen at

TCGA-IB-8127

Clinical Information

Hx: Suspicion of pancreatic adenocarcinoma
Infectious patient: No
Immunocompromised: No
History of neoplasm: No

Diagnosis

A: Liver Biopsy:

- Benign bile duct hamartoma
- Negative for malignancy

B: Gallbladder, Cholecystectomy:

- Chronic cholecystitis, negative for atypia
- Congested cystic duct lymph node, negative for malignancy

C: Portal Lymph Nodes:

- Reactive changes, negative for malignancy

Cc:

Chart Request ID:
Print Date/Time:

Pathology: Provider - Permanent
Page 1 of 5

[page 2 of 5]
MRN:
PHN:
ACB:

Surgical Pathology Report

Accession Number:
Collected Date:
Pathologist:

D: Head of Pancreas (Whipple's Resection):

- Invasive duct carcinoma of the pancreas, with focal extension to uncinate process margin
- Ulceration of the distal common bile duct and ampulla, with carcinoma invading through duodenal muscularis propria at the level of the ampulla
- Metastatic pancreatic carcinoma in three of 24 peripancreatic lymph nodes

Reported by:

Electronically signed by:

Synoptic Report

D: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades ampulla of Vater or sphincter of Oddi

Tumor invades peripancreatic soft tissues

MARGINS:

Margin(s) involved by invasive carcinoma

Uncinate process (retroperitoneal) margin (nonperitonealized surface of the uncinate process)

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

Not known

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

Not identified

PRIMARY TUMOR (pT):

Cc:

Chart Request ID:
Print Date/Time:

Pathology: Provider - Permanent
Page 2 of 5

[page 3 of 5]
MRN:
PHN:
ACB:

Surgical Pathology Report

Inquiry

Accession Number:

Collected Date:

Pathologist:

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 24

Number involved: 3

DISTANT METASTASIS (pM):

Not applicable

Gross Description

Received are specimens A to D. All requisitions and specimen containers are labelled with the patient's name
The cassettes and AP identifiers are labelled with the Surgical Number

A. The specimen consists of a liver biopsy which measures 1.0 x 0.5 x 0.5 cm. All tissue is submitted for QS in one block. [REDACTED]

B. The specimen consists of an unopened gallbladder measuring 9.5 cm in length and up to 2.5 cm in transverse diameter. The outer surface is unremarkable. Sectioning reveals pale green mucoid contents containing small flecks of yellow calculous debris measuring up to 0.2 cm in size. The mucosa is smooth and velvety. A cystic duct lymph node, 1.2 cm in greatest dimension, is present at the neck of the gallbladder. Representative sections of the neck, body and fundus are submitted in B1. The cystic duct lymph node is submitted in B2. [REDACTED]

C. The specimen consists of three fragments of tissue measuring 3.7 cm, 3.0 cm, and 0.9 cm in greatest dimension respectively. The largest fragment appears to consist of adipose tissue only and no lymph node is recognizable. Two representative sections are submitted in C1. The second largest fragment consists entirely of a firm yellow lymph node-like sample. Two sections are submitted in C2 and C3. The smallest fragment is submitted in C4 in its entirety. [REDACTED]

D. The specimen consists of a pancreaticoduodenectomy specimen in which the distal stomach to distal duodenal resection margin distance is 23.0 cm. The attached head of pancreas measures approximately 8.0 x 5.0 x 6.0 cm. A region of the ampulla is distorted by what appears to be a zone of ulceration into an underlying mass in the head of the pancreas. The distal common bile duct opens at this area and appears to be up to 1.3 cm in diameter. The duodenal wall around this area appears congested and indurated. Sectioning of the head of the pancreas shows a hard tumor mass surrounding the common bile duct and measuring 4.5 x 3.5 x approximately 4.0 cm. The carcinoma lies close to the uncinate process but also appears to encroach on the posterior surgical margin adjacent to the duodenum; this latter area is painted orange. The uncinate process margin is painted blue.

Sections are taken as follows:

[page 4 of 5]
MRN:
PHN:
ACB:

Inquiry Number

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

- D1 - proximal bile duct margin.
- D2 - pancreatic neck resection margin.
- D3 - distal duodenal margin, en face.
- D4 and D5 - ampulla edge (D5 with posterior margin).
- D6 and D7 - indurated posterior margin.
- D8 through D12 - tumor with uncinate margin.
- D13 - tumor in relation to overlying duodenum.
- D14 - tumor in relation to overlying proximal duodenal mucosa.
- D15 - proximal, gastric resection margin.
- D16 and D17 - six possible lymph nodes from distal lesser curve.
- D18 - three possible lymph nodes in pancreaticoduodenal chain.
- D19 through D21 - 11 possible lymph nodes at the inferior aspect of the head of pancreas.

Frozen Section Diagnosis

A. Liver Biopsy:

- Bile duct hamartoma.
- Negative for malignancy.

Reported by:

Microscopic Description

A: Sections after routine processing confirm the frozen section diagnosis. A small cluster of bile ducts form a localized nodule with no cytologic atypia.

B: Sections show mild chronic cholecystitis, but no cytologic atypia. The cystic duct lymph node is congested, but no sign of malignancy is present.

C: Fragments of adipose tissue include small nerve trunks. The large lymph node-like fragment is comprised of lymph nodes showing focal lipogranulomatosis. No sign of metastatic disease is present.

D: The head of pancreas is largely replaced by an invasive moderately differentiated pancreatic duct carcinoma. The tumor shows varying growth patterns ranging from well defined glandular spaces through to irregular tongues and islands of carcinoma with prominent nuclear pleomorphism. Many areas show clear cytoplasm consistent with mucinous differentiation. The carcinoma invades to the zone of the ampulla where the surface of the bile duct is large eroded and

Cc:

Chart Request IC

Print Date/Time:

Pathology: Provider - Permanent
Page 4 of 5

[page 5 of 5]
MRN:
PHN:
ACB:

Inquiry Number

Physical Pathology Report

Accession Number:

Collected Date:

Pathologist:

replaced by granulation tissue. The carcinoma elements extend through the muscularis propria of the duodenum at the level of the ampulla. Carcinoma focally extends to the uncinata process margin, but does not directly involve the posterior soft tissue margin. Carcinoma focally extends beyond the confines of the pancreas into peripancreatic adipose tissue. Adjacent pancreatic parenchyma shows prominent inflammation and fibrosis. The en face section of the neck of the pancreas is negative as is the proximal bile duct margin. Eight lymph nodes are incorporated in the sections of pancreas, one of which shows metastatic pancreatic adenocarcinoma. There are 16 lymph nodes dissected from the peripancreatic fatty tissue with metastatic duct carcinoma in two, one of which is in the pancreatoduodenal zone and one in a lymph node along inferior margin.

Cc:

Source: NCI Genomic Data Commons file 0464a9d1-5386-43fb-850b-e9d5edf5f164 (TCGA-IB-8127.C26DBE28-7E0C-4E51-8F54-C14CF4F16086.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).